Somatic mutation profile of tumor specimen TCGA-XU-A92R-01A (aliquot TCGA-XU-A92R-01A-11D-A423-09) from TCGA case TCGA-XU-A92R, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 76.6 years (27,971 days).
Specimen TCGA-XU-A92R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 616518de-e220-48b0-ba14-541d59508014.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92R-10A (Blood Derived Normal), aliquot TCGA-XU-A92R-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/796970e8-8a5d-4723-a483-fc31b20baeb1

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 61/654 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- CENPI | c.1444T>G p.F482V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54500752; called by muse, mutect2, varscan2
- CSMD2 | c.3733C>T p.R1245W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs762757595, COSV53949691, COSV53956378; called by muse, mutect2, varscan2
- GTF3C1 | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as rs778526776, COSV100649049; called by muse, mutect2, varscan2
- NAA10 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64170815; called by muse, mutect2, varscan2
- RAD54L | c.599T>G p.L200R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748823721; called by muse, mutect2, varscan2
- TECTA | c.1510G>C p.V504L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV50705758; called by muse, mutect2
- TLDC2 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs147062113; called by muse, mutect2, varscan2
- APOL5 | c.743T>C p.M248T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- DNAH9 | c.8256C>A p.S2752R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFM1 | c.1647T>A p.Y549* | Nonsense Mutation (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2, varscan2
- RAB3IP | c.1166G>A p.C389Y (on ENST00000550536 / NM_175623.4; = p.C373Y on NM_022456.5) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TRIM9 | c.106A>C p.N36H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- UTRN | c.8032G>T p.V2678L | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2
- APOB | c.11814T>C p.D3938= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs1180839017; called by muse, mutect2, varscan2
- CATSPERD | c.1797C>T p.D599= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs758592581; called by muse, mutect2, varscan2
- ELF1 | c.1107G>A p.R369= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2
- GPC1 | c.801C>G p.P267= | Silent (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- PCDHA13 | c.720G>A p.P240= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs782434208; called by muse, mutect2, varscan2
